Gene-level copy-number profile of tumor specimen ALCH-B2BR-TTP1-A from ALCHEMIST case ALCH-B2BR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.2 years (23,071 days).
Specimen ALCH-B2BR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4788413a-cd09-4a6d-a10f-2c34512ff050.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2BR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f5591e2c-67c2-408f-ab0f-9f650a6cc594

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 7,042; copy number 2: 51,325; copy number 3: 450; copy number 4: 11; copy number 5: 17; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:160,187,367–160,238,735, 2 genes: FABP6, FABP6-AS1.
- chr6:106,969,831–107,051,586, 2 genes: CD24, MTRES1.
- chr7:43,940,895–44,041,892, 9 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP.
- chr7:76,389,334–76,442,071, 2 genes: SSC4D, ZP3.
- chr7:149,053,961–149,226,238, 7 genes: COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282.
- chr17:2,712,309–2,749,504, 5 genes (within-gene range 0–1): AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:22,090,743–22,332,410, 7 genes: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr17:61,354,763–61,400,243, 3 genes (within-gene range 0–2): AC005746.3, AC005746.2, AC005746.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,399,784–31,415,315, 1 gene, copy number 5 (within-gene range 3–5): MICA.
- chr6:31,402,152–31,402,250, 1 gene, copy number 5 (within-gene range 3–5): Y_RNA.
- chr9:136,728,953–136,829,466, 14 genes, copy number 5 (within-gene range 3–5): AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1.
- chr9:136,812,788–136,815,536, 1 gene, copy number 5 (within-gene range 3–5): NCLP1.
- chr14:104,857,792–104,858,836, 1 gene, copy number 6: AL583810.1.

Autosomal genes at a single copy (total copy number 1): 4,226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
